Somatic mutation profile of tumor specimen TCGA-VQ-A8PE-01A (aliquot TCGA-VQ-A8PE-01A-11D-A410-08) from TCGA case TCGA-VQ-A8PE, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 78.7 years (28,755 days).
Specimen TCGA-VQ-A8PE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7f83ecb-e7a3-4a16-991f-22a136c5a52f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PE-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PE-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce4fb4e2-e375-4d93-bfdd-e571386b982d

The open-access MAF lists 128 somatic variants for this specimen: 98 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 28, Nonsense Mutation 9, Frame Shift Del 4, Splice Site 2, In Frame Del 1, 5'Flank 1, In Frame Ins 1, Translation Start Site 1, Intron 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 14/24 reads (58%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs746685392, COSV56642005, COSV56643302; called by muse, mutect2, varscan2
- ADAMTS14 | c.2303C>G p.P768R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.166); catalogued as COSV100941391; called by muse, mutect2, varscan2
- ADCY8 | c.1930A>G p.R644G | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV53897137, COSV53932150; called by muse, mutect2, varscan2
- AGPAT4 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100211014; called by muse, mutect2, varscan2
- AMELY | c.202G>A p.G68S (on ENST00000383036 / NM_001364814.1; = p.G54S on NM_001143.1) | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99293442; called by muse, mutect2, varscan2
- AMIGO3 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV100246446; called by muse, mutect2, varscan2
- ANKRD30A | c.608A>G p.K203R (on ENST00000611781; = p.K147R on NM_052997.2) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.131); catalogued as COSV64604232, COSV64607964; called by muse, mutect2
- APC | c.2896A>G p.S966G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57349827, COSV57397870; called by muse, mutect2, varscan2
- APLP1 | c.1792G>A p.V598I (on ENST00000221891 / NM_001024807.3; = p.V597I on NM_005166.4) | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.379); catalogued as rs1309406965, COSV99697517; called by muse, mutect2, varscan2
- ATP8A2 | c.2158C>T p.R720* | Nonsense Mutation (SNP) | VAF 15/100 reads (15%) | catalogued as rs1566306570, COSV54964589; called by muse, mutect2, varscan2
- CACNA2D4 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs748328734, COSV99765124, COSV99766442; called by muse, mutect2, varscan2
- CAVIN1 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567776298, COSV63812204; called by muse, mutect2, varscan2
- CDH22 | c.1603T>C p.Y535H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.69); catalogued as COSV64839024; called by muse, mutect2, varscan2
- CDK12 | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs1202425882, COSV101420372; called by muse, mutect2, varscan2
- CLCA4 | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1251631486, COSV55367589; called by muse, mutect2
- COL14A1 | c.1738-1G>T p.X580_splice | Splice Site (SNP) | VAF 17/145 reads (12%) | catalogued as COSV52859624, COSV99918142; called by muse, mutect2, varscan2
- CSNK2A2 | c.680T>G p.I227S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99345165; called by muse, varscan2
- CYP7B1 | c.184T>G p.L62V | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as COSV100040924; called by muse, mutect2, varscan2
- DAAM1 | c.1299G>C p.K433N | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100658173; called by muse, mutect2, varscan2
- DCDC1 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100662777; called by muse, mutect2
- DENND4B | c.2095C>G p.P699A | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100768445; called by muse, mutect2
- DLD | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.146); catalogued as COSV99226838; called by muse, mutect2, varscan2
- DPY19L2 | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100116541, COSV60541746; called by muse, mutect2, varscan2
- FAM13C | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs745920675, COSV53253932, COSV53254029; called by muse, mutect2, varscan2
- FMNL1 | c.2691C>A p.F897L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100056208; called by muse, mutect2, varscan2
- FPR2 | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100389134; called by muse, mutect2, varscan2
- FRY | c.3291G>C p.M1097I | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV100968833; called by muse, mutect2, varscan2
- FSTL5 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs200491447, COSV100053026; called by muse, mutect2, varscan2
- GABRG1 | c.583T>A p.F195I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54951589, COSV99777472; called by muse, mutect2, varscan2
- GDPD3 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.141); catalogued as rs1337544118, COSV99531256; called by muse, mutect2, varscan2
- GFUS | c.756C>G p.I252M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99643326; called by muse, mutect2, varscan2
- GPATCH8 | c.3004A>T p.R1002* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100132481; called by muse, mutect2
- GPR37 | c.1130C>A p.S377Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.82); catalogued as COSV100390543, COSV100390561; called by muse, mutect2, varscan2
- GTF2H1 | c.575T>C p.I192T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.336); catalogued as COSV99786324; called by muse, mutect2, varscan2
- IDO1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs767234834, COSV53712895, COSV99503100; called by muse, mutect2, varscan2
- IGF2BP2 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV99063380; called by muse, mutect2, varscan2
- IGLV1-47 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.409); catalogued as rs768931849; called by muse, mutect2, varscan2
- ILK | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as rs774113906, COSV100196138, COSV100196755; called by muse, mutect2, varscan2
- KANK4 | c.2711T>A p.V904D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747964044, COSV100443099; called by mutect2, varscan2
- KLHDC10 | c.1042C>G p.L348V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100110866, COSV59052918; called by muse, mutect2, varscan2
- LRATD1 | c.197A>G p.E66G | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99707003; called by muse, mutect2, varscan2
- MTOR | c.6674A>G p.Y2225C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100815750; called by muse, mutect2, varscan2
- MUC16 | c.13799C>T p.T4600I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.537); catalogued as COSV101198337, COSV67476710; called by muse, mutect2, varscan2
- NBEA | c.7781del p.P2594Lfs*6 | Frame Shift Del (DEL) | VAF 32/96 reads (33%) | catalogued as COSV59785302; called by mutect2, pindel, varscan2
- NDST1 | c.2204C>A p.T735N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as COSV99938640; called by muse, mutect2, varscan2
- NDUFAF5 | c.950G>C p.R317T | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV100962032; called by muse, mutect2
- NXPE4 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/61 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV100970315; called by muse, mutect2, varscan2
- OR4S2 | c.213C>A p.Y71* | Nonsense Mutation (SNP) | VAF 29/150 reads (19%) | catalogued as COSV100412565, COSV100412687, COSV56746668; called by muse, mutect2, varscan2
- PAQR9 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.588); catalogued as rs1044773965, COSV100503697; called by muse, mutect2, varscan2
- PCBP4 | c.851C>G p.A284G (on ENST00000322099 / NM_033010.2; = p.A241G on NM_020418.4) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV100436913; called by muse, mutect2, varscan2
- PCDH10 | c.2884G>A p.D962N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.612); catalogued as COSV52091877, COSV99993060; called by muse, mutect2, varscan2
- PCDH15 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.025); catalogued as rs753457449, COSV100226452, COSV57270179; called by muse, mutect2, varscan2
- PDE1B | c.225A>T p.T75= | Splice Region (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99672191; called by muse, mutect2
- PEX1 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754529845, COSV50395596, COSV50406081; called by muse, mutect2, varscan2
- PHACTR2 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs908882595, COSV59860645; called by muse, mutect2, varscan2
- PIAS2 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as rs867192877, COSV100245043; called by muse, mutect2
- PLB1 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs750364063, COSV100214838; called by muse, mutect2, varscan2
- PRG4 | c.2795C>T p.T932I | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.469); catalogued as COSV100798105; called by muse, mutect2, varscan2
- RBBP7 | c.78T>G p.N26K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101198267, COSV101198286; called by muse, mutect2, varscan2
- RETSAT | c.800-1G>A p.X267_splice | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99805894; called by muse, mutect2, varscan2
- SAMD15 | c.631C>G p.Q211E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.428); catalogued as COSV53628107, COSV99374787; called by muse, mutect2, varscan2
- SBNO1 | c.1904G>T p.G635V (on ENST00000420886; = p.G634V on NM_018183.5) | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99928776; called by muse, mutect2, varscan2
- SCYL3 | c.1866G>T p.K622N (on ENST00000367770; = p.K568N on NM_020423.7) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99609437; called by muse, mutect2
- SHROOM3 | c.883C>T p.L295F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs757969587, COSV99933597; called by muse, mutect2, varscan2
- SIPA1L3 | c.4036G>A p.G1346R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.511); catalogued as rs764077337, COSV99727435; called by muse, mutect2, varscan2
- SLC1A6 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1430616951, COSV55667690; called by muse, mutect2
- SLC25A1 | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as CM132519, COSV99310880; called by muse, mutect2, varscan2
- SLC4A11 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs770563344, COSV66260714; called by muse, mutect2, varscan2
- SLC6A15 | c.714G>T p.M238I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99880218; called by muse, mutect2, varscan2
- SMC2 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV99658447; called by muse, mutect2, varscan2
- SMO | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1307431013, COSV50828671; called by muse, mutect2, varscan2
- SNX16 | c.359A>C p.E120A | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100629503; called by muse, mutect2, varscan2
- SORCS1 | c.1666A>G p.N556D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV99543654; called by muse, mutect2, varscan2
- STAB1 | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as rs373323793; called by muse, mutect2, varscan2
- SYNCRIP | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100784011; called by muse, mutect2, varscan2
- TENM4 | c.7939G>A p.V2647I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs184305763, COSV53678552; called by muse, mutect2, varscan2
- THSD7B | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs1457774852, COSV99745022; called by muse, mutect2, varscan2
- THSD7B | c.3860C>T p.P1287L (on ENST00000272643; = p.P1285L on NM_001316349.2) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV99745025; called by muse, mutect2, varscan2
- TPM2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100253028; called by muse, mutect2, varscan2
- TRIM28 | c.2264A>G p.Y755C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99448727; called by muse, mutect2, varscan2
- TTI1 | c.13G>C p.D5H | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100989583; called by muse, mutect2, varscan2
- U2SURP | c.2474T>A p.M825K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1267009567, COSV101204344; called by muse, mutect2, varscan2
- UBAC2 | c.945G>T p.E315D (on ENST00000403766 / NM_001144072.2; = p.E280D on NM_177967.4) | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT tolerated (0.2); PolyPhen benign (0.127); catalogued as COSV100854119; called by muse, mutect2, varscan2
- UBASH3B | c.598A>T p.T200S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV99416901; called by muse, mutect2, varscan2
- USF3 | c.3038A>C p.K1013T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as COSV100324759; called by muse, mutect2, varscan2
- USP29 | c.2003A>C p.K668T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.28); catalogued as COSV99517722; called by muse, mutect2
- WASF3 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs1292057978, COSV58968133; called by muse, mutect2
- ZFHX4 | c.10560C>A p.C3520* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99254597; called by muse, mutect2, varscan2
- ZNF292 | c.6343C>T p.R2115* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as rs866467799, COSV60535418; called by muse, mutect2, varscan2
- ZNF585A | c.1414G>A p.G472R (on ENST00000292841 / NM_001288800.2; = p.G417R on NM_152655.3) | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99492762; called by muse, mutect2
- ZNF615 | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as rs758427092, COSV65035135; called by muse, mutect2, varscan2
- E2F3 | c.1163_1172del p.S388Kfs*28 | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | called by mutect2, pindel*, varscan2*
- ESRRG | c.988_990del p.Y330del | In Frame Del (DEL) | VAF 18/35 reads (51%) | called by mutect2, pindel, varscan2
- PBK | c.755_756insCGATGATGA p.D254_D256dup | In Frame Ins (INS) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- SLC9A8 | c.257del p.F86Sfs*11 | Frame Shift Del (DEL) | VAF 19/183 reads (10%) | called by mutect2, pindel, varscan2
- SMAD4 | c.1616_1632del p.V539Dfs*32 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- TENM1 | c.5057_5058dup p.D1687* | Frame Shift Ins (INS) | VAF 27/82 reads (33%) | called by mutect2, pindel, varscan2
- ADAMTS14 | c.732G>A p.L244= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1296294480, COSV100941390; called by muse, mutect2, varscan2
- ADCK5 | c.1068C>T p.F356= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV100450226; called by muse, mutect2, varscan2
- AGBL5 | c.1155C>T p.N385= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as rs113809750; ClinVar: likely benign; called by muse, mutect2, varscan2
- BAD | c.480C>T p.G160= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99657130; called by mutect2, varscan2
- CDH2 | c.786C>T p.D262= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV52293642, COSV99295822; called by muse, mutect2, varscan2
- DOK3 | c.954C>T p.N318= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs779292845, COSV57251751; called by muse, mutect2, varscan2
- DTNBP1 | c.48C>T p.F16= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs1419475106, COSV100160391; called by muse, mutect2, varscan2
- FSD2 | c.1734C>T p.T578= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100575021; called by muse, mutect2, varscan2
- FXR1 | c.366A>G p.K122= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99976132; called by muse, mutect2, varscan2
- GBP1 | c.366G>A p.L122= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as rs1313667480, COSV100976222; called by muse, mutect2
- GPC5 | c.354A>T p.A118= | Silent (SNP) | VAF 34/48 reads (71%) | catalogued as COSV100992884; called by muse, mutect2, varscan2
- IQCN | c.3366C>T p.S1122= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs775816174, COSV100828190; called by muse, mutect2, varscan2
- LRP1B | c.5898C>T p.N1966= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1277540813, COSV101253162; called by muse, mutect2
- NBEA | c.2193G>A p.S731= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs769776727; called by muse, varscan2
- PCDHAC1 | c.1056C>T p.D352= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs1012110026, COSV99165080; called by muse, mutect2
- PGD | c.1284C>T p.S428= | Silent (SNP) | VAF 52/90 reads (58%) | catalogued as COSV54623539; called by muse, mutect2, varscan2
- PRKAG1 | c.459G>A p.L153= | Silent (SNP) | VAF 9/246 reads (4%) | catalogued as COSV100304908; called by muse, mutect2
- RAB20 | c.117C>T p.G39= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1307097548, COSV99940807; called by muse, mutect2, varscan2
- SLC4A3 | c.1839G>A p.P613= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs747034568, COSV56091245; called by muse, mutect2, varscan2
- SPATA31A3 | c.1869G>A p.L623= | Silent (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- TLN1 | c.6648T>A p.L2216= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100147350; called by muse, mutect2, varscan2
- TOR1B | c.558C>A p.I186= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV52214219, COSV99399998; called by muse, mutect2, varscan2
- TRPS1 | c.2076C>T p.Y692= (on ENST00000220888 / NM_001330599.2; = p.Y705= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV99628662; called by muse, mutect2
- USF3 | c.2886A>C p.S962= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV100324761, COSV57072805; called by muse, mutect2, varscan2
- USP9Y | c.4554C>G p.L1518= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100168212; called by muse, mutect2, varscan2
- VSNL1 | c.63G>A p.E21= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV99722881; called by muse, mutect2, varscan2
- ZFHX4 | c.2721T>C p.A907= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs761106000, COSV99257025; called by muse, mutect2, varscan2
- ZNF560 | c.183C>T p.V61= | Silent (SNP) | VAF 36/149 reads (24%) | catalogued as COSV100038260; called by muse, mutect2, varscan2
- IFT46 | c.46-710_46-709dup | Intron (INS) | VAF 20/106 reads (19%) | called by mutect2, varscan2
- Y_RNA | chr7:75516204 T>C | 5'Flank (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
